Gene-level copy-number profile of tumor specimen TCGA-GC-A3RB-01A from TCGA case TCGA-GC-A3RB, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 54.8 years (20,021 days).
Specimen TCGA-GC-A3RB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.30ef048d-f4ce-4730-9407-3bd795c7fd4f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GC-A3RB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/334e6e32-6fc4-4957-83e9-e5309812b498

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 572; copy number 2: 14,204; copy number 3: 29,040; copy number 4: 10,989; copy number 5: 2,544; copy number 6: 624; copy number 7: 236; copy number 8: 678; copy number 9: 394; copy number 10: 35; copy number 11: 99; copy number 12: 154; copy number 14: 52; copy number 15: 36; copy number 17: 22; copy number 18: 55; copy number 23: 46; copy number 63: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GC-A3RB-01A-12D-A21Y-01): tumor purity 0.85, ploidy 3.2, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,833 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,813,225–153,380,799, 200 genes, copy number 9–12 (broad region; genes not listed).
- chr2:119,429,901–121,182,580, 31 genes, copy number 7 (within-gene range 5–7): TMEM37, SCTR, SCTR-AS1, CFAP221, TMEM177, RPL17P15, PTPN4, RPL27P7, EPB41L5, AC012363.1, Y_RNA, MTATP6P26, MTCO3P43, MTND3P10, MTND4LP14, MTND4P26, MTND5P28, TMEM185B, RALB, AC012363.2, INHBB, LINC01101, AC073257.2, AC073257.1, Y_RNA, AC018866.1, GLI2, AC017033.1, Y_RNA, AC067960.1, AC079988.1.
- chr3:7,951,263–10,708,007, 74 genes, copy number 7 (broad region; genes not listed).
- chr3:12,004,388–12,434,356, 7 genes, copy number 8: SYN2, ACTG1P12, TIMP4, MTCO1P5, GSTM5P1, PPARG, AC091492.1.
- chr3:16,802,651–18,444,817, 12 genes, copy number 7 (within-gene range 2–7): PLCL2, MIR3714, PLCL2-AS1, AC090644.1, TBC1D5, AC090960.1, AC140076.1, RNU7-10P, AC104451.1, AC104451.2, AC104297.1, PDCL3P3.
- chr3:170,222,424–171,900,749, 30 genes, copy number 7 (within-gene range 5–7): PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11, AC026316.4, MIR6828, SLC7A14-AS1, SLC7A14, KRT8P13, AC026316.1, AC026316.3, AC026316.5, AC026316.2, RPL22L1, EIF5A2, AC061708.1, KLF7P1, RNU1-70P, SLC2A2, TNIK, MIR569, Y_RNA, AC092919.1, AC092919.2, RNU6-348P, AC008134.1, PLD1, TMEM212-AS1.
- chr3:179,452,395–183,910,936, 95 genes, copy number 7–11 (broad region; genes not listed).
- chr3:195,996,262–196,027,694, 1 gene, copy number 8 (within-gene range 5–8): AC024937.3.
- chr3:196,027,183–196,662,004, 33 genes, copy number 8: TFRC, AC024937.1, RNU7-18P, LINC00885, ZDHHC19, Y_RNA, SLC51A, PCYT1A, AC069257.3, AC069257.1, TCTEX1D2, AC069257.2, TM4SF19-TCTEX1D2, TM4SF19-AS1, TM4SF19, RNU6-910P, UBXN7, RNU6-1279P, RN7SL434P, RN7SL738P, AC083822.1, UBXN7-AS1, AC117490.1, RNF168, AC117490.2, SMCO1, AC092933.1, RPS29P3, WDR53, FBXO45, AC092933.2, LINC01063, NRROS.
- chr6:17,759,183–23,125,087, 59 genes, copy number 7–18 (within-gene range 4–18): KIF13A, AL023807.1, NHLRC1, TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1, AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P.
- chr6:56,056,590–57,646,850, 20 genes, copy number 11 (within-gene range 3–11): COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1.
- chr6:61,240,898–61,241,311, 1 gene, copy number 8: AL356131.1.
- chr6:111,483,511–111,598,302, 1 gene, copy number 8 (within-gene range 6–8): TRAF3IP2-AS1.
- chr6:111,555,381–111,873,452, 3 genes, copy number 8 (within-gene range 2–8): TRAF3IP2, Z97989.1, FYN.
- chr6:123,803,865–136,792,477, 197 genes, copy number 7–18 (broad region; genes not listed).
- chr7:54,933,699–57,194,068, 107 genes, copy number 9–63 (broad region; genes not listed).
- chr8:86,707,547–120,373,573, 458 genes, copy number 8 (broad region; genes not listed).
- chr8:126,325,454–131,432,869, 67 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr10:1,957,589–2,189,512, 7 genes, copy number 8 (within-gene range 3–8): AL355597.1, LINC00700, AL441943.1, MIR6072, RNU6-889P, AL441943.2, LINC02662.
- chr10:3,748,966–10,462,361, 125 genes, copy number 7–12 (broad region; genes not listed).
- chr10:10,798,397–12,328,389, 25 genes, copy number 7 (within-gene range 5–7): CELF2, LINC00710, AL136369.2, AL136369.1, AL162408.1, CELF2-AS2, AL136320.1, CELF2-AS1, AC026887.1, USP6NL, AL512631.2, AL512631.1, ECHDC3, PROSER2, PROSER2-AS1, UPF2, RNU6-1095P, DHTKD1, RNU6-88P, SEC61A2, MIR548AK, NUDT5, CDC123, AL512770.1, RN7SL198P.
- chr10:20,779,973–23,586,224, 62 genes, copy number 9 (broad region; genes not listed).
- chr12:111,304,142–112,509,918, 40 genes, copy number 7–15: MIR6760, RNA5SP373, PHETA1, LINC02356, HSPA8P14, SH2B3, ATXN2, U7, IFITM3P5, ATXN2-AS, BRAP, PCNPP1, ACAD10, AC002996.1, ALDH2, MIR6761, MAPKAPK5-AS1, MAPKAPK5, RPS2P41, ADAM1A, ADAM1B, TMEM116, SLC25A3P2, AC004024.1, ERP29, AC073575.2, NAA25, MIR3657, AC073575.1, Y_RNA, TRAFD1, Y_RNA, HECTD4, MIR6861, AC004217.1, RN7SKP71, RPL7AP60, AC004217.2, RPL6, PTPN11.
- chr13:107,531,171–107,531,248, 1 gene, copy number 10: MIR1267.
- chr13:109,101,261–110,513,209, 25 genes, copy number 7–15 (within-gene range 5–15): MYO16-AS2, MYO16-AS1, AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2, AL390755.3, COL4A1, AL161773.1, COL4A2, MIR8073, COL4A2-AS2, COL4A2-AS1.
- chr14:26,208,036–26,208,424, 1 gene, copy number 8: CYB5AP5.
- chr17:29,255,839–30,906,238, 83 genes, copy number 9 (broad region; genes not listed).
- chr19:27,638,483–30,909,155, 68 genes, copy number 17–23 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 572. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
